Somatic mutation profile of tumor specimen TARGET-10-PARLPA-09A (aliquot TARGET-10-PARLPA-09A-01D) from TARGET case TARGET-10-PARLPA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.5 years (6,040 days).
Specimen TARGET-10-PARLPA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d96f87b-ab61-454f-84bd-7057b9bd97db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARLPA-10A (Blood Derived Normal), aliquot TARGET-10-PARLPA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13aabe93-39f8-4610-b7ee-c4043298f642

The open-access MAF lists 30 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 1, Intron 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 49/136 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CAMSAP3 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as COSV50337007, COSV50339414; called by muse, mutect2, varscan2
- CLDN25 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs946050881; called by muse, mutect2, varscan2
- DOK2 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1157982032, COSV52390134; called by muse, mutect2, varscan2
- PCDHB6 | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 59/256 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs782123595, COSV50693258; called by muse, mutect2, varscan2
- USP2 | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 54/145 reads (37%) | catalogued as COSV52730185; called by muse, mutect2, varscan2
- ADCY1 | c.1984-1G>A p.X662_splice | Splice Site (SNP) | VAF 31/58 reads (53%) | called by muse, mutect2, varscan2
- AGAP1 | c.1299C>A p.S433R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); called by muse, mutect2
- BCL2L12 | c.77A>C p.H26P | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.087); called by muse, mutect2
- CAMSAP2 | c.343A>T p.T115S | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CCDC168 | c.18778G>T p.D6260Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2
- DDX46 | c.124A>C p.S42R | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- GTF3C3 | c.2140del p.Q714Kfs*12 | Frame Shift Del (DEL) | VAF 80/233 reads (34%) | called by mutect2, pindel, varscan2
- IGLV5-45 | c.122G>C p.C41S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- LAMC3 | c.926A>C p.Q309P | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- OCLN | c.110C>A p.P37Q | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.145); called by muse, mutect2
- PJA1 | c.1439G>T p.G480V (on ENST00000361478 / NM_145119.4; = p.G292V on NM_022368.5) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.1); called by muse, mutect2
- SCN11A | c.1508A>G p.Q503R | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- THOC5 | c.478G>T p.V160F | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ULK2 | c.1522+1G>T p.X508_splice | Splice Site (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2
- VEZF1 | c.1524G>T p.M508I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); called by muse, mutect2
- WNK4 | c.2483T>C p.I828T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EGLN3 | c.405C>T p.H135= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as rs376568155; called by muse, mutect2, varscan2
- MYH4 | c.4743T>C p.A1581= | Silent (SNP) | VAF 31/144 reads (22%) | called by muse, mutect2, varscan2
- RS1 | c.213C>T p.F71= | Silent (SNP) | VAF 50/95 reads (53%) | catalogued as rs764292483; called by muse, mutect2, varscan2
- THBS2 | c.2982G>A p.S994= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs191971795, COSV64681599; called by muse, mutect2, varscan2
- TMEM74B | c.414G>T p.V138= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- CD99 | c.*50C>A | 3'UTR (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- CICP28 | chr7:56811981 A>C | 3'Flank (SNP) | VAF 9/54 reads (17%) | catalogued as rs781998069; called by muse, varscan2
- HMGCLL1 | c.198+13204T>C | Intron (SNP) | VAF 28/152 reads (18%) | catalogued as rs773690986; called by muse, mutect2
